Somatic mutation profile of tumor specimen MMRF_1703_1_BM_CD138pos (aliquot MMRF_1703_1_BM_CD138pos_T2_KBS5U_K11934) from MMRF case MMRF_1703, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.5 years (27,212 days).
Specimen MMRF_1703_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2347835a-6936-4512-95fe-9ea89a8eff16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1703_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1703_1_PB_Whole_C7_KBS5U_K11895; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a58d89c-4e62-4c51-a190-28ee47a6ed1c

The open-access MAF lists 61 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 13, Intron 8, Silent 8, 5'UTR 6, 5'Flank 2, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10466G>A p.R3489Q | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369135279; called by muse, mutect2
- ARMH4 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767508866; called by muse, mutect2, varscan2
- DZANK1 | c.1115G>A p.C372Y (on ENST00000262547 / NM_001099407.1; = p.C173Y on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1292686393; called by muse, mutect2
- IGHJ3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 26/39 reads (67%) | PolyPhen benign (0); catalogued as rs183030857; called by muse, varscan2
- IGHJ4 | c.1T>C p.Y1H | Missense Mutation (SNP) | VAF 42/52 reads (81%) | PolyPhen benign (0.023); catalogued as rs375553834; called by muse, varscan2
- IGHV1-24 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 87/108 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs781788468; called by muse, mutect2, varscan2
- KLHL17 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770775850; called by muse, mutect2, varscan2
- PPL | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs373692481; called by muse, mutect2, varscan2
- SLC9C2 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1553254329; called by muse, mutect2
- SYDE1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs552062430; called by muse, mutect2, varscan2
- ZDHHC2 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as rs751890279; called by muse, mutect2, varscan2
- AK7 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- CCDC120 | c.1303_1306dup p.L436Pfs*36 | Frame Shift Ins (INS) | VAF 51/65 reads (78%) | called by mutect2, pindel, varscan2
- CCND1 | c.91A>C p.M31L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERBIN | c.2240G>C p.S747T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL24 | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP3K12 | c.1305_1306del p.R435Sfs*9 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- MLPH | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.704); called by muse, mutect2
- MYLK | c.2030A>G p.Q677R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- N4BP1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- PCDH11Y | c.778C>G p.Q260E (on ENST00000400457 / NM_032973.2; = p.Q249E on NM_032971.3) | Missense Mutation (SNP) | VAF 134/150 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PCDHGB1 | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STX3 | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- COL5A2 | c.3582G>A p.G1194= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs140022057; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRX | c.309G>A p.Q103= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs138242846; called by muse, mutect2, varscan2
- KCNS3 | c.447G>A p.S149= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs1238471772, COSV58407889; called by muse, mutect2
- KIAA2026 | c.615G>T p.T205= | Silent (SNP) | VAF 68/185 reads (37%) | catalogued as COSV67354383; called by muse, mutect2, varscan2
- PCNX1 | c.6252A>T p.G2084= | Silent (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- SYNPO2 | c.3336T>C p.Y1112= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs777964245; called by muse, mutect2, varscan2
- WWC2 | c.2271T>C p.V757= | Silent (SNP) | VAF 83/171 reads (49%) | called by muse, mutect2, varscan2
- ZNF800 | c.363T>C p.Y121= | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- AKAP13 | c.*606A>G | 3'UTR (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- BBC3 | c.-71del | 5'UTR (DEL) | VAF 69/200 reads (35%) | called by mutect2, pindel, varscan2
- BCAT1 | c.*3194A>T | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, varscan2
- BDP1 | c.-173C>T | 5'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- CDC25C | c.290-104C>G | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- CORO2A | c.*3710_*3712del | 3'UTR (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- CXCL13 | c.279-106A>G | Intron (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- DLL3 | c.*415C>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- DNAH2 | c.1170+754G>A | Intron (SNP) | VAF 29/82 reads (35%) | catalogued as rs1178453234; called by muse, mutect2, varscan2
- EQTN | c.376+80C>T | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- ERBB4 | c.*6934G>A | 3'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- GABRD | c.*34C>T | 3'UTR (SNP) | VAF 20/47 reads (43%) | catalogued as rs372342447; called by muse, mutect2, varscan2
- GLIS3 | c.*3333_*3366delinsTTTTTTTTTTTTTTTTTTTCCAACAGATAAAG | 3'UTR (DEL) | VAF 4/46 reads (9%) | called by pindel, varscan2*
- KCNB2 | c.-26G>C | 5'UTR (SNP) | VAF 72/204 reads (35%) | called by muse, mutect2, varscan2
- KCNK2 | c.-3C>T | 5'UTR (SNP) | VAF 110/368 reads (30%) | catalogued as COSV101223210; called by muse, mutect2, varscan2
- KRAS | c.*2193G>A | 3'UTR (SNP) | VAF 39/88 reads (44%) | catalogued as rs1390720112; called by muse, mutect2, varscan2
- LRATD1 | c.*4028T>A | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- MORN1 | chr1:2391600 G>T | 5'Flank (SNP) | VAF 36/81 reads (44%) | catalogued as rs1030016090; called by muse, mutect2, varscan2
- MTSS2 | c.1129-53G>A | Intron (SNP) | VAF 12/35 reads (34%) | catalogued as rs1344133864; called by muse, mutect2, varscan2
- SERP1 | c.*1831T>C | 3'UTR (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- SLITRK6 | c.*676C>T | 3'UTR (SNP) | VAF 7/77 reads (9%) | catalogued as rs999307932; called by muse, mutect2
- TECPR1 | c.*1482G>A | 3'UTR (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- TMEM131 | c.-286G>T | 5'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- TMSB4X | c.-16-199T>A | Intron (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2
- TMSB4X | c.-16-197T>C | Intron (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2
- TNNT2 | chr1:201373305 G>C | 5'Flank (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- TPD52L1 | c.-106G>A | 5'UTR (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- UFM1 | c.*149T>G | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- ZNF692 | c.-13+239C>T | Intron (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
